Somatic mutation profile of tumor specimen TCGA-V1-A8WN-01A (aliquot TCGA-V1-A8WN-01A-11D-A377-08) from TCGA case TCGA-V1-A8WN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8WN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b1e72ab-b151-42f0-99fe-097b0dc58f4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8WN-10A (Blood Derived Normal), aliquot TCGA-V1-A8WN-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5de7a27e-3544-4ea8-9be0-a3ee30548249

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP2C9 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs375805362; called by muse, mutect2, varscan2
- DHX30 | c.2522A>T p.D841V (on ENST00000445061 / NM_138615.3; = p.D802V on NM_014966.3) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as COSV99275957; called by muse, mutect2, varscan2
- KCNC4 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1261102442, COSV100873669; called by muse, mutect2, varscan2
- MAMLD1 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as rs1445530999, COSV53372117; called by muse, mutect2, varscan2
- PCDHA6 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.135); catalogued as rs782284717, COSV65349504; called by muse, mutect2
- POSTN | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs1285552885, COSV65712077; called by muse, mutect2, varscan2
- RALGAPA1 | c.5672A>G p.D1891G | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99355608; called by muse, mutect2, varscan2
- S100Z | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.114); catalogued as COSV100461258; called by muse, mutect2
- SLC25A51 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 29/124 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs760638785, COSV99643401; called by muse, mutect2, varscan2
- TRPM7 | c.1207A>G p.T403A | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV57916965; called by muse, mutect2, varscan2
- TUBB4A | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs1367784980, COSV51170288; called by muse, mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- ADCY10 | c.276C>T p.D92= | Silent (SNP) | VAF 45/277 reads (16%) | catalogued as rs1402674921, COSV100897004; called by muse, mutect2, varscan2
- GAL3ST1 | c.1053C>T p.A351= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1351086553, COSV100143187; called by muse, mutect2, varscan2
- KIAA1586 | c.627A>G p.E209= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100875378; called by muse, mutect2, varscan2
- TRBV27 | c.279C>T p.F93= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
